Somatic mutation profile of tumor specimen 0DE0TZ from CCDI case PBBNAN, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 13.0 years (4,764 days).
Specimen 0DE0TZ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3f3bd5cc-932f-4abe-b969-37d0d4d7f6b4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DE0QO (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/29384797-c276-447e-8351-0ccfbb41e3be

The open-access MAF lists 38 somatic variants for this specimen: 27 protein-altering or splice-affecting, 6 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Silent 6, Intron 3, Nonsense Mutation 2, Frame Shift Ins 2, 3'UTR 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KDM6A | c.4051C>T p.R1351* | Nonsense Mutation (SNP) | VAF 44/400 reads (11%) | catalogued as rs1318649487, CM138471, COSV65038966; ClinVar: pathogenic; called by muse, varscan2
- ABCC3 | c.2600C>T p.A867V | Missense Mutation (SNP) | VAF 56/818 reads (7%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs760451698, COSV53321394; called by muse, mutect2
- ADGRE2 | c.1576C>T p.H526Y | Missense Mutation (SNP) | VAF 103/239 reads (43%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as rs758041727; called by muse, mutect2, varscan2
- ADGRL2 | c.4144C>T p.P1382S (on ENST00000370717 / NM_001366005.1; = p.P1326S on NM_012302.4) | Missense Mutation (SNP) | VAF 162/932 reads (17%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.999); catalogued as COSV54661823; called by mutect2, varscan2
- AKT1 | c.763G>A p.A255T | Missense Mutation (SNP) | VAF 45/491 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs375395037; ClinVar: uncertain significance; called by muse, mutect2
- ATP10B | c.1900A>C p.S634R | Missense Mutation (SNP) | VAF 185/433 reads (43%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.891); catalogued as rs1030873423; called by muse, mutect2, varscan2
- BCL9 | c.2308G>A p.G770S | Missense Mutation (SNP) | VAF 256/405 reads (63%) | SIFT tolerated (0.53); PolyPhen benign (0.444); catalogued as rs1553205047, COSV99324905; called by muse, mutect2, varscan2
- CASP10 | c.838C>T p.R280W (on ENST00000272879 / NM_032974.5; = p.R237W on NM_001230.5) | Missense Mutation (SNP) | VAF 141/371 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); catalogued as rs1351292534; called by muse, mutect2, varscan2
- CTAGE9 | c.242C>T p.T81M | Missense Mutation (SNP) | VAF 114/356 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs1222753640; called by muse, varscan2
- DUSP29 | c.442G>A p.V148I | Missense Mutation (SNP) | VAF 38/500 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.109); catalogued as rs190150687, COSV58299971; called by muse, mutect2
- FREM2 | c.7430G>A p.R2477Q | Missense Mutation (SNP) | VAF 54/676 reads (8%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.637); catalogued as rs148032830; called by muse, mutect2
- IBSP | c.652G>A p.G218R | Missense Mutation (SNP) | VAF 153/313 reads (49%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as rs746206406, COSV56896516; called by muse, mutect2, varscan2
- TIGD2 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 22/716 reads (3%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as COSV100392360; called by muse, mutect2
- WNK4 | c.1863G>A p.S621= | Splice Region (SNP) | VAF 91/357 reads (25%) | catalogued as rs768940964; called by muse, mutect2, varscan2
- APC2 | c.5870C>A p.A1957E | Missense Mutation (SNP) | VAF 67/158 reads (42%) | SIFT tolerated (0.91); PolyPhen benign (0.356); called by muse, mutect2, varscan2
- CASR | c.769G>C p.E257Q | Missense Mutation (SNP) | VAF 106/315 reads (34%) | SIFT tolerated (0.43); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- CSNK1A1L | c.25G>T p.A9S | Missense Mutation (SNP) | VAF 24/774 reads (3%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0); called by muse, mutect2
- FCRLA | c.112G>C p.V38L (on ENST00000367959; = p.V21L on NM_032738.4) | Missense Mutation (SNP) | VAF 22/668 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.001); called by muse, mutect2
- FRMD4B | c.316G>T p.D106Y | Missense Mutation (SNP) | VAF 190/477 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- OBSCN | c.5195A>G p.E1732G | Missense Mutation (SNP) | VAF 49/679 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.018); called by muse, mutect2
- PIK3C2G | c.3827C>G p.T1276R (on ENST00000676171; = p.T1235R on NM_004570.5) | Missense Mutation (SNP) | VAF 332/727 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.203); called by muse, mutect2, varscan2
- PRDM2 | c.1312G>T p.E438* | Nonsense Mutation (SNP) | VAF 231/386 reads (60%) | called by muse, mutect2, varscan2
- SETD2 | c.913dup p.T305Nfs*4 | Frame Shift Ins (INS) | VAF 172/620 reads (28%) | called by mutect2, varscan2
- SLC3A1 | c.73G>T p.V25F | Missense Mutation (SNP) | VAF 38/335 reads (11%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- SMPD4 | c.632C>A p.P211H | Missense Mutation (SNP) | VAF 61/438 reads (14%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.779); called by muse, mutect2, varscan2
- TAP1 | c.1007T>C p.F336S | Missense Mutation (SNP) | VAF 79/370 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- TTN | c.18507dup p.L6170Ifs*6 (on ENST00000591111; = p.L5243Ifs*6 on NM_133378.4 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 192/403 reads (48%) | called by mutect2, varscan2
- ARX | c.72C>T p.L24= | Silent (SNP) | VAF 35/197 reads (18%) | called by muse, mutect2, varscan2
- DSG1 | c.549C>T p.D183= | Silent (SNP) | VAF 299/732 reads (41%) | catalogued as rs200895473; called by muse, mutect2, varscan2
- NEB | c.5304T>C p.D1768= | Silent (SNP) | VAF 329/740 reads (44%) | catalogued as COSV51423971; called by muse, mutect2, varscan2
- OR4C5 | c.720C>T p.V240= | Silent (SNP) | VAF 145/512 reads (28%) | called by muse, mutect2, varscan2
- SREBF2 | c.756C>G p.S252= | Silent (SNP) | VAF 128/438 reads (29%) | catalogued as COSV63333000; called by muse, mutect2, varscan2
- TAPBP | c.501C>T p.A167= | Silent (SNP) | VAF 56/802 reads (7%) | catalogued as rs1268750547; called by muse, mutect2
- CDK8 | c.*51T>C | 3'UTR (SNP) | VAF 43/95 reads (45%) | called by muse, mutect2, varscan2
- OLFML3 | c.400+43A>C | Intron (SNP) | VAF 34/122 reads (28%) | called by mutect2, varscan2
- SLC41A3 | c.274-5451C>T | Intron (SNP) | VAF 168/378 reads (44%) | catalogued as rs752352667, COSV59990537; called by muse, mutect2, varscan2
- SYNE1 | c.25788+94T>C | Intron (SNP) | VAF 62/222 reads (28%) | catalogued as rs1187610939; called by muse, mutect2, varscan2
- TTC23 | c.*37C>A | 3'UTR (SNP) | VAF 10/264 reads (4%) | called by muse, mutect2
